Somatic mutation profile of tumor specimen ALCH-B3ZL-TTP1-A (aliquot ALCH-B3ZL-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3ZL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 74.0 years (27,038 days).
Specimen ALCH-B3ZL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 161aab56-493a-4c41-98e4-4c7462f5c259.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ZL-NB1-A (Blood Derived Normal), aliquot ALCH-B3ZL-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f3d0492-1072-4b2f-b6f6-263605476f70

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGF5 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV56889840; called by muse, mutect2
- ARMC10 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, varscan2
- HEBP2 | c.420-786A>G | Intron (SNP) | VAF 5/49 reads (10%) | catalogued as rs1562240867; called by muse, mutect2
